Somatic mutation profile of tumor specimen MP2PRT-PAVWHU-TMP1-A (aliquot MP2PRT-PAVWHU-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVWHU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.8 years (1,395 days).
Specimen MP2PRT-PAVWHU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dc9715a-0fed-4e62-8be3-c7ebab23d750.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWHU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWHU-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4ecb55f-2c8e-448b-ae65-e8a0e0950d33

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP3 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 23/730 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1225680362; called by muse, mutect2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by muse, mutect2, varscan2
- BMP7 | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 11/346 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- SETBP1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 67/454 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SH3RF3 | c.1963C>T p.Q655* | Nonsense Mutation (SNP) | VAF 262/746 reads (35%) | called by muse, mutect2, varscan2
- ZDBF2 | c.3057C>T p.N1019= | Silent (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
